Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4964, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4964-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal mass.

TCGA-BP-4964

Specimens Submitted:

- 1: Kidney, right, nephrectomy
- 2: Lymph nodes, precaval nodes and paracaval nodes, resection
- 3: Adrenal gland, right, adrenalectomy

DIAGNOSIS:

1. Kidney, right, nephrectomy
Tumor Type: Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:
Nuclear grade II/IV

Tumor Size:
Greatest diameter is 3.9 cm.

Local Invasion (for renal cortical types):
Not Identified
the tumor abuts the renal sinus

Renal Vein Invasion:
Not identified

Surgical Margins:
Free of tumor

Non-Neoplastic Kidney:
Focal chronic inflammation

Adrenal Gland:
Not identified

Lymph Nodes:
Not identified

Staging for renal cell carcinoma/oncocytoma:
pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

2. Lymph nodes, precaval nodes and paracaval nodes, resection
Lymph Nodes:

[page 2 of 3]
Not involved
Number of nodes examined:11
Number of metastatic nodes:0

3. Adrenal gland, right, adrenalectomy

Adrenal gland, unremarkable.
One benign lymph node. (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen section consultation labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 317.0 g in total. The kidney measures 9.6 x 6.6 x 4.0 cm. The attached ureter measures 5.0 cm in length and 0.3 cm in diameter. The attached renal vein measures 3.0 cm in length and 0.6 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a variegated yellow and hemorrhagic well-circumscribed mass with cystic areas measuring 3.9 x 3.0 x 2.9 cm. The lesion abuts but does not invade the capsule, and compresses the renal pelvis. The mass is located in the mid region adjacent to the pelvis. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. No definitive lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
F--adipose tissue
FSC-frozen section control

2). The specimen is received in formalin is labeled "pre-caval and paracaval lymph nodes" and consists of multiple lymph nodes with attached fat measuring 4.0 x 3.5 x 0.4 cm in aggregate. Entirely submitted.

Summary of sections:

LN-lymph nodes

3). The specimen is received in formalin is labeled "right adrenal gland" and consists of an adrenal gland with attached fat measuring 7.0 x 2.5 x 0.4 cm. Each from the weight of the adrenal gland is 10.5 g. On cut section the adrenal gland has an unremarkable cortex and medulla. An attached soft tan black lymph node is identified to the surface of the adrenal measuring 2.0 x 1.5 x 0.5 cm. Representative sections are submitted.

Summary of sections:

A--adrenal gland
L-lymph node

[page 3 of 3]
Summary of Sections:

Part 1: Kidney, right, nephrectomy

Block	Sect. Site	PCs
1	f	1
1	fsc	1
1	k	1
2	rp	2
6	t	6
1	tk	1
2	tsf	2
1	uvm	1

Part 2: Lymph nodes, precaval nodes and paracaval nodes, resection

Block	Sect. Site	PCs
6	ln	6

Part 3: Adrenal gland, right, adrenalectomy

Block	Sect. Site	PCs
2	a	2
1	l	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CONVENTIONAL TYPE.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 2ffb8778-2bdb-4b69-a0f8-48c284cfe44f (TCGA-BP-4964.DD8002FA-7CA0-40B5-9D9D-307522EF4D16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).